Gene-level copy-number profile of tumor specimen AP-3FY5-2T from APOLLO case AP-3FY5, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3.
Specimen AP-3FY5-2T: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d722b854-4754-45d6-925e-22fdcf332bed.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-3FY5-93 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/00aa9b67-dac9-4b2e-a54b-2611246b4622

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 43; copy number 2: 2,435; copy number 3: 13,614; copy number 4: 14,024; copy number 5: 13,418; copy number 6: 8,642; copy number 7: 1,819; copy number 8: 2,748; copy number 9: 665; copy number 10: 519; copy number 11: 125; copy number 12: 206; copy number 13: 31; copy number 14: 10; copy number 15: 33; copy number 17: 31.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,369,394–65,285,209, 23 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5.
- chr17:31,094,927–31,382,116, 7 genes (within-gene range 0–3): NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,620 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,050,441–152,601,086, 269 genes, copy number 10–12 (broad region; genes not listed).
- chr1:158,694,539–173,207,331, 389 genes, copy number 10–17 (broad region; genes not listed).
- chr1:173,714,941–174,995,308, 26 genes, copy number 10: KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT, RABGAP1L, AL022400.1, GPR52, BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1.
- chr1:180,906,651–181,182,208, 10 genes, copy number 10: LINC02816, KIAA1614, AL162431.1, KIAA1614-AS1, AL162431.2, AL162431.3, STX6, MR1, IER5, LINC01732.
- chr1:182,096,338–185,634,182, 80 genes, copy number 9 (broad region; genes not listed).
- chr2:38,814–9,003,709, 119 genes, copy number 9–15 (broad region; genes not listed).
- chr2:27,889,941–28,338,901, 1 gene, copy number 12 (within-gene range 3–12): BABAM2.
- chr2:28,134,408–33,399,509, 89 genes, copy number 10–12 (broad region; genes not listed).
- chr2:36,299,388–38,377,285, 42 genes, copy number 11: RPL21P36, CRIM1-DT, CRIM1, AC007378.1, FEZ2, AC007363.1, VIT, STRN, AC007382.1, RNU6-577P, HEATR5B, GPATCH11, EIF2AK2, ARL14EPP1, SULT6B1, RPL31P16, CEBPZOS, CEBPZ, AC007390.1, NDUFAF7, PRKD3, AC007391.1, RNU6-939P, QPCT, RNU6-1116P, AC006369.1, CDC42EP3, AC006369.2, AC010878.1, LINC00211, RMDN2, RMDN2-AS1, CYP1B1, CYP1B1-AS1, AC009229.4, AC009229.2, RNU6-951P, AC009229.3, AC009229.1, RPL7P12, GAPDHP25, ATL2.
- chr2:45,164,816–45,323,397, 1 gene, copy number 9 (within-gene range 8–9): LINC01121.
- chr2:45,169,616–48,314,224, 59 genes, copy number 9 (within-gene range 7–9): AC009236.2, AC009236.1, SRBD1, RN7SL414P, PRKCE, PRKCE-AS1, RPL26P15, AC017006.2, AC017006.1, RPL36AP14, Metazoa_SRP, EPAS1, LINC01820, LINC02583, AC016912.2, AC016912.1, RN7SL817P, TMEM247, ATP6V1E2, RHOQ, RHOQ-AS1, PIGF, CRIPT, AC020604.1, LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP, MSH2, KCNK12, MSH2-OT1, AC079250.1, MSH6, NME2P2, AC006509.1, U6, FBXO11, RPL36AP15, RPS27AP7, AC079807.1, AC092650.1, PPIAP62, VN1R18P.
- chr2:74,832,655–74,893,359, 2 genes, copy number 10: AC019069.1, HK2.
- chr5:795,606–1,816,048, 35 genes, copy number 9: ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6.
- chr8:102,648,784–134,979,279, 394 genes, copy number 9 (broad region; genes not listed).
- chr10:4,871,901–4,891,975, 1 gene, copy number 9: AKR1C6P.
- chr11:644,233–798,281, 12 genes, copy number 10 (within-gene range 5–10): DEAF1, AC131934.1, EPS8L2, TMEM80, AP006621.4, TALDO1, GATD1, AP006621.3, AP006621.5, AP006621.2, CEND1, SLC25A22.
- chr15:84,053,113–85,794,925, 70 genes, copy number 9 (broad region; genes not listed).
- chr19:4,903,080–5,456,856, 8 genes, copy number 11 (within-gene range 6–11): UHRF1, MIR4747, KDM4B, PTPRS, AC022517.1, RPL32P34, AC005790.1, ZNRF4.
- chr19:28,790,812–29,233,385, 13 genes, copy number 10–14: MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P.

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
